Somatic mutation profile of tumor specimen TCGA-QK-A6VB-01A (aliquot TCGA-QK-A6VB-01A-12D-A34J-08) from TCGA case TCGA-QK-A6VB, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Floor of mouth, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 66.1 years (24,144 days).
Specimen TCGA-QK-A6VB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e0821502-437a-4cd8-900c-8e4f3efa28f3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-QK-A6VB-10B (Blood Derived Normal), aliquot TCGA-QK-A6VB-10B-01D-A34M-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b7935147-df1a-4ee6-bb47-9079e4b877d5

The open-access MAF lists 525 somatic variants for this specimen: 403 protein-altering or splice-affecting, 111 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 274, Silent 111, Frame Shift Del 70, Frame Shift Ins 32, In Frame Del 9, Splice Site 8, Nonsense Mutation 8, Intron 5, 5'Flank 3, 3'UTR 2, Splice Region 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BLM | c.1544del p.N515Mfs*16 | Frame Shift Del (DEL) | VAF 30/96 reads (31%) | catalogued as rs367543043; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- IDH2 | c.419G>A p.R140Q | Missense Mutation (SNP) | VAF 24/90 reads (27%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as rs121913502, CM106818, COSV57468751, COSV57469541; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.1003C>T p.R335* | Nonsense Mutation (SNP) | VAF 76/101 reads (75%) | hotspot (GDC flag); catalogued as rs121909231, CM971278, COSV64288687, COSV64297951; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.659A>G p.Y220C | Missense Mutation (SNP) | VAF 24/47 reads (51%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912666, CM015378, CM951227, COSV52661282, COSV52677517; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.559+1G>A p.X187_splice | Splice Site (SNP) | VAF 47/99 reads (47%) | hotspot (GDC flag); catalogued as rs1131691042, CS137624, COSV52670017, COSV52686439, COSV52695669; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCF3 | c.1640G>A p.G547D | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99491583; called by muse, mutect2, varscan2
- ACAD11 | c.1293G>T p.E431D | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.341); catalogued as COSV99392367; called by muse, mutect2, varscan2
- ACAN | c.103del p.Q35Nfs*5 | Frame Shift Del (DEL) | VAF 19/115 reads (17%) | catalogued as COSV61363906; called by mutect2, pindel, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 36/129 reads (28%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADCK1 | c.316C>A p.L106M | Missense Mutation (SNP) | VAF 23/154 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99452211; called by muse, mutect2, varscan2
- AHDC1 | c.578C>A p.P193H | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.905); catalogued as COSV99899579; called by muse, mutect2, varscan2
- AHNAK2 | c.10202T>C p.M3401T | Missense Mutation (SNP) | VAF 233/592 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); catalogued as rs1357421951, COSV100318348; called by muse, mutect2, varscan2
- AHNAK2 | c.9093del p.S3032Lfs*13 | Frame Shift Del (DEL) | VAF 82/403 reads (20%) | catalogued as rs746543823; called by mutect2, varscan2
- AHRR | c.788G>A p.R263Q | Missense Mutation (SNP) | VAF 37/64 reads (58%) | SIFT tolerated (0.71); PolyPhen benign (0.009); catalogued as rs749711222, COSV57088478; called by muse, mutect2, varscan2
- ALG10 | c.587G>A p.C196Y | Missense Mutation (SNP) | VAF 148/333 reads (44%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.87); catalogued as COSV99848257; called by muse, mutect2, varscan2
- ALG8 | c.545A>G p.Q182R | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.147); catalogued as rs745715068, COSV100220213; called by muse, mutect2, varscan2
- ALS2 | c.1427_1428del p.E476Gfs*71 | Frame Shift Del (DEL) | VAF 40/144 reads (28%) | catalogued as rs386134176; called by pindel, varscan2
- AMFR | c.634G>A p.G212R | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs756140159, COSV51922109, COSV99316110; called by muse, mutect2, varscan2
- ANKDD1A | c.813G>T p.E271D | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT tolerated (0.26); PolyPhen benign (0.015); catalogued as COSV60352838; called by muse, mutect2, varscan2
- APAF1 | c.634T>C p.F212L (on ENST00000551964 / NM_181861.2; = p.F201L on NM_001160.3) | Missense Mutation (SNP) | VAF 26/159 reads (16%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as COSV100244286; called by muse, mutect2, varscan2
- APOA4 | c.741_743del p.K247del | In Frame Del (DEL) | VAF 32/94 reads (34%) | catalogued as rs765377610; called by pindel, varscan2
- AQP7 | c.700dup p.R234Pfs*61 | Frame Shift Ins (INS) | VAF 26/88 reads (30%) | catalogued as rs3215969; called by mutect2, varscan2
- ARHGAP33 | c.2029C>T p.P677S | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.104); catalogued as COSV99139157; called by muse, mutect2, varscan2
- ARID1B | c.6285G>T p.Q2095H | Missense Mutation (SNP) | VAF 37/478 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV99270716; called by muse, mutect2
- ARMC12 | c.618+1G>A p.X206_splice (on ENST00000373866 / NM_001286574.2; = p.X233_splice on NM_145028.5) | Splice Site (SNP) | VAF 20/110 reads (18%) | catalogued as COSV99849534; called by muse, mutect2, varscan2
- ARNTL | c.86G>A p.G29D | Missense Mutation (SNP) | VAF 14/119 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.045); catalogued as COSV100724818; called by muse, mutect2, varscan2
- ASCC3 | c.1399G>A p.G467R | Missense Mutation (SNP) | VAF 53/117 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as rs772379539, COSV61230780; called by muse, mutect2, varscan2
- ASCL1 | c.481C>T p.R161C | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1055293109, COSV57152329, COSV99902107; called by muse, mutect2, varscan2
- ASPM | c.2942C>T p.T981I | Missense Mutation (SNP) | VAF 20/133 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.175); catalogued as rs763886024, COSV54123796, COSV99659493; called by muse, mutect2, varscan2
- ATL1 | c.818G>A p.G273D | Missense Mutation (SNP) | VAF 5/84 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100613217; called by muse, mutect2
- BCORL1 | c.5042del p.P1681Qfs*20 | Frame Shift Del (DEL) | VAF 47/71 reads (66%) | catalogued as rs768244116; called by mutect2, pindel, varscan2
- BEST3 | c.1332del p.R445Gfs*40 | Frame Shift Del (DEL) | VAF 42/123 reads (34%) | catalogued as rs779566914, COSV58300788; called by mutect2, pindel, varscan2
- BIN1 | c.383C>T p.T128M | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.351); catalogued as rs756882994, COSV99388125; called by muse, mutect2, varscan2
- BRICD5 | c.28C>T p.R10C | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); catalogued as rs547524671, COSV100063822; called by muse, mutect2, varscan2
- BRINP2 | c.492G>T p.K164N | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV100838228; called by muse, mutect2, varscan2
- C19orf57 | c.1126G>A p.A376T | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs771802249, COSV100694778; called by muse, mutect2, varscan2
- C20orf204 | c.391A>G p.T131A | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.33); catalogued as COSV99412445; called by muse, mutect2, varscan2
- C2orf88 | c.251A>G p.Y84C | Missense Mutation (SNP) | VAF 38/173 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs780426934, COSV100502888; called by muse, mutect2, varscan2
- CASD1 | c.2347dup p.C783Lfs*12 | Frame Shift Ins (INS) | VAF 12/84 reads (14%) | catalogued as rs777757305; called by mutect2, varscan2
- CASP8 | c.802G>A p.G268R (on ENST00000432109 / NM_033355.3; = p.G285R on NM_001228.4) | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV99965674; called by muse, mutect2
- CBLB | c.979G>A p.G327R | Missense Mutation (SNP) | VAF 47/147 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99913926; called by muse, mutect2, varscan2
- CBX2 | c.1062G>T p.Q354H | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.006); catalogued as rs1285377681, COSV99490957; called by muse, mutect2, varscan2
- CCDC25 | c.621C>A p.F207L | Missense Mutation (SNP) | VAF 43/83 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100738306; called by muse, mutect2, varscan2
- CCDC33 | c.434C>T p.T145I | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as rs778073465, COSV100351704; called by muse, mutect2, varscan2
- CCDC40 | c.1544C>T p.A515V | Missense Mutation (SNP) | VAF 55/115 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0.251); catalogued as rs774455448, COSV99482057; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CCER1 | c.268G>T p.G90W | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.406); catalogued as COSV100727105; called by muse, mutect2, varscan2
- CDH7 | c.878C>T p.A293V | Missense Mutation (SNP) | VAF 34/125 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV59886372; called by muse, mutect2, varscan2
- CEP131 | c.221G>T p.R74I | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); catalogued as COSV99488692; called by muse, mutect2, varscan2
- CEP20 | c.53del p.K18Rfs*4 | Frame Shift Del (DEL) | VAF 21/188 reads (11%) | catalogued as rs746479678; called by mutect2, pindel, varscan2
- CEP41 | c.803G>T p.G268V | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99782821; called by muse, mutect2, varscan2
- CEP89 | c.2135G>T p.R712I | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1198483735, COSV99993781; called by muse, mutect2, varscan2
- CFAP61 | c.1852G>A p.V618M | Missense Mutation (SNP) | VAF 42/245 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs747883044, COSV99845882; called by muse, mutect2, varscan2
- CLSPN | c.770G>T p.G257V | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.9); catalogued as COSV99231090; called by muse, mutect2, varscan2
- CNTRL | c.3377A>G p.Q1126R | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs143318973; called by muse, mutect2, varscan2
- COBLL1 | c.2834del p.L945Cfs*12 (on ENST00000392717; = p.L907Cfs*12 on NM_014900.5) | Frame Shift Del (DEL) | VAF 24/74 reads (32%) | catalogued as rs374805044; called by mutect2, varscan2
- COL22A1 | c.1220G>A p.R407H | Missense Mutation (SNP) | VAF 47/77 reads (61%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs770249679, COSV100279616; called by muse, mutect2, varscan2
- COL24A1 | c.4670A>G p.D1557G | Missense Mutation (SNP) | VAF 12/164 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100993711; called by muse, mutect2
- COQ5 | c.701G>A p.R234Q | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756543334, COSV99942417; called by muse, mutect2, varscan2
- CORO6 | c.758A>G p.N253S | Missense Mutation (SNP) | VAF 12/142 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.013); catalogued as COSV100801372, COSV61470513; called by muse, mutect2
- CPN2 | c.946C>T p.R316C | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.448); catalogued as rs777829016, COSV60469465; called by muse, mutect2, varscan2
- CREG2 | c.839A>G p.E280G | Missense Mutation (SNP) | VAF 70/173 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV100240587; called by muse, mutect2, varscan2
- CSMD2 | c.808G>A p.G270R | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.229); catalogued as rs369990781; called by muse, mutect2, varscan2
- CSNK1D | c.344G>A p.R115H | Missense Mutation (SNP) | VAF 31/174 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV53924049; called by muse, mutect2, varscan2
- CTIF | c.1690C>T p.R564W | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1165050224, COSV99838106; called by muse, mutect2, varscan2
- CTSW | c.760C>A p.L254M | Missense Mutation (SNP) | VAF 37/192 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.648); catalogued as COSV100327465; called by muse, mutect2, varscan2
- CUEDC1 | c.638C>T p.P213L | Missense Mutation (SNP) | VAF 29/117 reads (25%) | SIFT tolerated (0.34); PolyPhen benign (0.086); catalogued as rs754174777, COSV100804793; called by muse, mutect2, varscan2
- CYP39A1 | c.301G>A p.V101I | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT tolerated (0.22); PolyPhen benign (0.034); catalogued as rs540612754, COSV51495108, COSV51495942; called by muse, mutect2, varscan2
- DCAF4 | c.415G>A p.V139I | Missense Mutation (SNP) | VAF 37/246 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs201937947; called by muse, mutect2, varscan2
- DCC | c.3896A>G p.Q1299R | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as COSV101473404; called by muse, mutect2, varscan2
- DCLRE1A | c.1279A>G p.K427E | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs1395224393, COSV100800440; called by muse, mutect2, varscan2
- DCTN3 | c.115A>G p.K39E | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.725); catalogued as COSV99426977; called by muse, mutect2, varscan2
- DDX4 | c.1870T>C p.Y624H | Missense Mutation (SNP) | VAF 79/101 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100737651; called by muse, mutect2, varscan2
- DENND11 | c.949G>A p.A317T | Missense Mutation (SNP) | VAF 23/40 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101530724; called by muse, mutect2, varscan2
- DENND1C | c.847G>A p.E283K | Missense Mutation (SNP) | VAF 22/140 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV101200236; called by muse, mutect2, varscan2
- DHX36 | c.460del p.M154Cfs*27 | Frame Shift Del (DEL) | VAF 36/62 reads (58%) | catalogued as rs373108427; called by mutect2, varscan2
- DLGAP4 | c.2665C>T p.Q889* (on ENST00000339266 / NM_001365621.1; = p.Q886* on NM_014902.6) | Nonsense Mutation (SNP) | VAF 31/150 reads (21%) | catalogued as COSV100211463; called by muse, mutect2, varscan2
- DNAH2 | c.70C>T p.R24W | Missense Mutation (SNP) | VAF 22/41 reads (54%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.454); catalogued as rs145790522; called by muse, mutect2, varscan2
- DNAJC15 | c.164G>A p.R55H | Missense Mutation (SNP) | VAF 37/47 reads (79%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.691); catalogued as rs768717251, COSV101004959; called by muse, mutect2, varscan2
- DOP1A | c.4502C>T p.A1501V | Missense Mutation (SNP) | VAF 30/131 reads (23%) | SIFT tolerated (0.99); PolyPhen benign (0.018); catalogued as COSV99382524; called by muse, mutect2, varscan2
- DPYSL5 | c.50T>C p.V17A | Missense Mutation (SNP) | VAF 18/188 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV99982607; called by muse, mutect2
- DRG1 | c.1007C>A p.A336D | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100513730; called by muse, mutect2, varscan2
- DSP | c.1094C>T p.T365I | Missense Mutation (SNP) | VAF 65/181 reads (36%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.984); catalogued as rs754577019, COSV101131541; called by muse, mutect2, varscan2
- DUS1L | c.698-3_698-2del p.X233_splice | Splice Site (DEL) | VAF 18/58 reads (31%) | catalogued as rs769804615; called by pindel, varscan2
- EGLN2 | c.652C>T p.R218C | Missense Mutation (SNP) | VAF 67/174 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.056); catalogued as rs140368149; called by muse, mutect2, varscan2
- EIF2AK3 | c.1643C>A p.P548H | Missense Mutation (SNP) | VAF 41/104 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.628); catalogued as COSV57549501; called by muse, mutect2, varscan2
- EIF3K | c.279+1G>A p.X93_splice | Splice Site (SNP) | VAF 7/57 reads (12%) | catalogued as rs776669619, COSV99943131; called by muse, mutect2, varscan2
- ELAVL2 | c.86T>C p.V29A | Missense Mutation (SNP) | VAF 23/202 reads (11%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.003); catalogued as COSV99806751; called by muse, mutect2, varscan2
- ENAH | c.1010C>A p.P337H | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as rs758306418, COSV99491143; called by muse, varscan2
- ENO1 | c.224C>A p.P75H | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as COSV99318911; called by muse, mutect2
- ERCC6 | c.835G>A p.A279T | Missense Mutation (SNP) | VAF 28/129 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.859); catalogued as COSV100876052; called by muse, mutect2, varscan2
- ERICH3 | c.2464G>A p.A822T | Missense Mutation (SNP) | VAF 32/114 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.202); catalogued as COSV100445075; called by muse, mutect2, varscan2
- ERO1B | c.1066C>T p.H356Y | Missense Mutation (SNP) | VAF 28/157 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as rs1558505629, COSV99934598; called by muse, mutect2, varscan2
- ESPN | c.433G>A p.A145T | Missense Mutation (SNP) | VAF 42/80 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs1241074178, COSV64704050; called by muse, mutect2, varscan2
- F13A1 | c.1601T>C p.F534S | Missense Mutation (SNP) | VAF 38/106 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV99343577; called by muse, mutect2, varscan2
- F5 | c.1940G>A p.R647H | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as rs140530655; called by muse, mutect2, varscan2
- FAM210B | c.451G>A p.V151M | Missense Mutation (SNP) | VAF 51/136 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs534520658, COSV100453113; called by muse, mutect2, varscan2
- FANCL | c.925A>G p.I309V | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV99287768; called by muse, mutect2, varscan2
- FASTKD3 | c.542C>T p.A181V | Missense Mutation (SNP) | VAF 20/189 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.158); catalogued as COSV99241926; called by muse, mutect2, varscan2
- FLG | c.7508C>T p.A2503V | Missense Mutation (SNP) | VAF 150/733 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.129); catalogued as rs780063414, COSV100911868; called by muse, mutect2, varscan2
- FRY | c.5692G>T p.G1898* | Nonsense Mutation (SNP) | VAF 4/42 reads (10%) | catalogued as COSV100969641; called by muse, mutect2
- GALNT6 | c.1816G>A p.A606T | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as COSV62541815; called by muse, mutect2
- GJC1 | c.46C>A p.H16N | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100395211; called by muse, mutect2, varscan2
- GLIS1 | c.344dup p.S117Ffs*15 | Frame Shift Ins (INS) | VAF 15/73 reads (21%) | catalogued as rs1177272637; called by mutect2, pindel, varscan2
- GPR142 | c.674A>G p.Q225R | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV100170916; called by muse, mutect2, varscan2
- GPR152 | c.109G>T p.V37L | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.023); catalogued as COSV100351598; called by muse, mutect2, varscan2
- GPRIN3 | c.397C>T p.H133Y | Missense Mutation (SNP) | VAF 64/134 reads (48%) | SIFT tolerated (0.27); PolyPhen benign (0.01); catalogued as COSV100310879; called by muse, mutect2, varscan2
- GRB14 | c.679A>G p.M227V | Missense Mutation (SNP) | VAF 40/113 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs1479833659, COSV99814273; called by muse, mutect2, varscan2
- GRIN1 | c.1144C>T p.P382S | Missense Mutation (SNP) | VAF 29/96 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100160539; called by muse, mutect2, varscan2
- GRIN2D | c.1987G>A p.A663T | Missense Mutation (SNP) | VAF 50/218 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99616741; called by muse, mutect2, varscan2
- GRM1 | c.2279A>T p.N760I | Missense Mutation (SNP) | VAF 33/156 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99267776; called by muse, mutect2, varscan2
- H4C1 | c.142T>C p.S48P | Missense Mutation (SNP) | VAF 40/128 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99772144; called by muse, mutect2, varscan2
- HAS3 | c.1300G>A p.A434T | Missense Mutation (SNP) | VAF 70/195 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.01); catalogued as COSV99544562; called by muse, mutect2, varscan2
- HCAR1 | c.939G>A p.M313I | Missense Mutation (SNP) | VAF 61/258 reads (24%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs775771821, COSV100811685; called by muse, mutect2, varscan2
- HCRT | c.74C>T p.A25V | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.035); catalogued as rs772136922, COSV99237639; called by muse, varscan2
- HEATR5A | c.2084C>T p.A695V | Missense Mutation (SNP) | VAF 22/129 reads (17%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV101120309; called by muse, mutect2, varscan2
- HECTD3 | c.1073-1G>T p.X358_splice | Splice Site (SNP) | VAF 61/192 reads (32%) | catalogued as COSV55799827, COSV99870341; called by muse, mutect2, varscan2
- HERC2 | c.7418G>T p.R2473M | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.188); catalogued as COSV99875532; called by muse, mutect2, varscan2
- HID1 | c.216G>T p.K72N | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV100586029; called by muse, varscan2
- HIRIP3 | c.1153C>A p.R385S | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.511); catalogued as COSV99663225; called by muse, mutect2, varscan2
- HIVEP2 | c.5638C>T p.H1880Y | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT tolerated (0.65); PolyPhen benign (0.265); catalogued as COSV99174726; called by muse, mutect2, varscan2
- HNRNPA3 | c.392G>A p.G131D | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.876); catalogued as COSV101182960; called by muse, mutect2, varscan2
- HOXC10 | c.548G>A p.R183H | Missense Mutation (SNP) | VAF 33/91 reads (36%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.662); catalogued as COSV100329123; called by muse, mutect2, varscan2
- HPS5 | c.1117G>A p.A373T (on ENST00000349215 / NM_181507.2; = p.A259T on NM_007216.4) | Missense Mutation (SNP) | VAF 39/250 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100752337, COSV61687897; called by muse, mutect2, varscan2
- HSPA8 | c.1918C>T p.P640S | Missense Mutation (SNP) | VAF 52/73 reads (71%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.901); catalogued as COSV99914518; called by muse, mutect2, varscan2
- ICAM1 | c.1202G>T p.R401M | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.232); catalogued as COSV99321025; called by muse, mutect2, varscan2
- IDH3A | c.343C>T p.R115C | Missense Mutation (SNP) | VAF 40/137 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100210949; called by muse, mutect2, varscan2
- IKBIP | c.752G>T p.S251I | Missense Mutation (SNP) | VAF 41/159 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.347); catalogued as COSV100689861; called by muse, mutect2, varscan2
- IL20RA | c.991G>T p.G331* | Nonsense Mutation (SNP) | VAF 48/111 reads (43%) | catalogued as COSV100360116, COSV57356223; called by muse, mutect2, varscan2
- IL21R | c.488G>C p.R163P | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.614); catalogued as rs148782015, COSV100560342; called by mutect2, varscan2
- IL7R | c.1172G>T p.R391M | Missense Mutation (SNP) | VAF 7/91 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.847); catalogued as COSV100286459, COSV57406766; called by muse, mutect2
- INPP5F | c.788dup p.Q264Sfs*8 | Frame Shift Ins (INS) | VAF 8/58 reads (14%) | catalogued as rs750419826; called by mutect2, varscan2
- ITPR2 | c.6958A>C p.I2320L | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.026); catalogued as COSV101190086; called by muse, mutect2, varscan2
- IVD | c.16A>G p.T6A (on ENST00000651168; = p.T3A on NM_002225.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.001); catalogued as COSV99991548; called by muse, mutect2, varscan2
- IWS1 | c.1302G>T p.K434N | Missense Mutation (SNP) | VAF 48/122 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.403); catalogued as COSV99767442; called by muse, mutect2, varscan2
- JKAMP | c.754A>G p.I252V (on ENST00000554271 / NM_001284201.1; = p.I238V on NM_016475.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as rs766089067, COSV54198614; called by muse, mutect2, varscan2
- KANK3 | c.1772G>A p.R591H | Missense Mutation (SNP) | VAF 29/58 reads (50%) | SIFT tolerated (0.35); PolyPhen benign (0.011); catalogued as rs911474222, COSV100445080; called by muse, mutect2, varscan2
- KBTBD4 | c.497C>T p.A166V | Missense Mutation (SNP) | VAF 31/247 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); catalogued as COSV55456480, COSV99772411; called by muse, mutect2, varscan2
- KCNB2 | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 28/157 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.297); catalogued as COSV101578881; called by muse, mutect2, varscan2
- KDM6B | c.4166-1G>T p.X1389_splice | Splice Site (SNP) | VAF 12/48 reads (25%) | catalogued as COSV99641950; called by muse, mutect2
- KIF13B | c.1364C>T p.A455V | Missense Mutation (SNP) | VAF 5/78 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV101580556; called by muse, mutect2
- KLHL42 | c.1194del p.C399Vfs*44 | Frame Shift Del (DEL) | VAF 45/246 reads (18%) | catalogued as rs749194179; called by mutect2, pindel, varscan2
- KYNU | c.596T>C p.L199S | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV99933628; called by muse, mutect2, varscan2
- LAMA5 | c.9191A>G p.Y3064C | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV99441238; called by muse, mutect2
- LEMD2 | c.1303C>T p.R435C | Missense Mutation (SNP) | VAF 59/136 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs755595754, COSV99540800; called by muse, mutect2, varscan2
- LGALS9 | c.32T>C p.L11P | Missense Mutation (SNP) | VAF 7/76 reads (9%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.715); catalogued as COSV100119496; called by muse, mutect2
- LGMN | c.226T>C p.Y76H | Missense Mutation (SNP) | VAF 35/212 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV100605916; called by muse, mutect2, varscan2
- LONRF1 | c.944C>T p.A315V | Missense Mutation (SNP) | VAF 35/151 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.349); catalogued as COSV101238248; called by muse, mutect2, varscan2
- LPA | c.5045G>T p.S1682I | Missense Mutation (SNP) | VAF 81/167 reads (49%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.6); catalogued as COSV100307526; called by muse, mutect2, varscan2
- LTN1 | c.4486C>T p.R1496W | Missense Mutation (SNP) | VAF 74/382 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs148488534; called by muse, mutect2, varscan2
- LUC7L3 | c.1091G>T p.R364M | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.962); catalogued as COSV99537071; called by muse, mutect2, varscan2
- MAEL | c.1049G>T p.R350M | Missense Mutation (SNP) | VAF 24/107 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as COSV100901908; called by muse, mutect2, varscan2
- MAN2A1 | c.3190A>G p.N1064D | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99811553; called by muse, mutect2, varscan2
- MAN2B1 | c.1478G>A p.C493Y | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV55472457; called by muse, mutect2
- MANSC1 | c.1204G>A p.V402I | Missense Mutation (SNP) | VAF 33/76 reads (43%) | SIFT tolerated (0.29); PolyPhen benign (0.068); catalogued as rs138511907; called by muse, mutect2, varscan2
- MAP3K11 | c.1044del p.E349Sfs*70 | Frame Shift Del (DEL) | VAF 7/33 reads (21%) | catalogued as COSV58419117; called by mutect2, pindel, varscan2
- MAP3K15 | c.3344C>T p.A1115V | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0.046); catalogued as COSV100135246; called by muse, mutect2, varscan2
- MAP3K9 | c.2879G>A p.R960H (on ENST00000554752 / NM_001284230.1; = p.R974H on NM_033141.4) | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.854); catalogued as rs1290657401, COSV101173714; called by muse, mutect2, varscan2
- MARK1 | c.272T>C p.I91T | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100857406; called by muse, mutect2, varscan2
- MASP2 | c.1099G>A p.G367S | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.791); catalogued as rs760512377, COSV101280326; called by muse, mutect2, varscan2
- MAST3 | c.2382G>T p.E794D | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV99445873; called by muse, mutect2, varscan2
- MCHR2 | c.623del p.F208Sfs*5 | Frame Shift Del (DEL) | VAF 66/176 reads (38%) | catalogued as rs759525627, COSV55999002; called by mutect2, varscan2
- MDC1 | c.1060C>T p.H354Y | Missense Mutation (SNP) | VAF 27/194 reads (14%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.522); catalogued as COSV100902991; called by muse, mutect2, varscan2
- MINK1 | c.510G>A p.V170= | Splice Region (SNP) | VAF 8/112 reads (7%) | catalogued as COSV100767213; called by muse, mutect2
- MLYCD | c.770T>C p.L257P | Missense Mutation (SNP) | VAF 19/100 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99299372; called by muse, mutect2, varscan2
- MPEG1 | c.1679del p.G560Afs*43 | Frame Shift Del (DEL) | VAF 26/97 reads (27%) | catalogued as rs777449563; called by mutect2, pindel, varscan2
- MPI | c.377C>T p.P126L | Missense Mutation (SNP) | VAF 35/65 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs765621023, COSV60396861; called by muse, mutect2, varscan2
- MTHFD1 | c.1373C>T p.A458V | Missense Mutation (SNP) | VAF 33/138 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs1283487328, COSV99386943; called by muse, mutect2, varscan2
- MYCBPAP | c.2353G>A p.V785M | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.039); catalogued as COSV99277186; called by muse, mutect2, varscan2
- MYH13 | c.1614G>T p.E538D | Missense Mutation (SNP) | VAF 40/165 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV99354786; called by muse, mutect2, varscan2
- MYH9 | c.536G>A p.G179D | Missense Mutation (SNP) | VAF 29/91 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99337955; called by muse, mutect2, varscan2
- MYO3A | c.3202G>T p.A1068S | Missense Mutation (SNP) | VAF 35/158 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.044); catalogued as COSV99780690; called by muse, mutect2, varscan2
- MYPN | c.3731A>G p.Y1244C | Missense Mutation (SNP) | VAF 81/113 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100590312; called by muse, mutect2, varscan2
- NARS2 | c.803G>A p.S268N | Missense Mutation (SNP) | VAF 21/100 reads (21%) | SIFT tolerated (0.35); PolyPhen benign (0.014); catalogued as COSV99807407; called by muse, mutect2, varscan2
- NBAS | c.3658G>A p.V1220I | Missense Mutation (SNP) | VAF 107/227 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.035); catalogued as rs543195772, COSV55718191; called by muse, mutect2, varscan2
- NBEA | c.298G>A p.V100I | Missense Mutation (SNP) | VAF 12/119 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs772091414, COSV100082475; called by muse, mutect2
- NBEAL2 | c.3368C>T p.T1123I | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs766062810, COSV99436882; called by muse, varscan2
- NCK2 | c.872C>T p.T291M | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs370241867; called by muse, mutect2, varscan2
- NCKAP5L | c.2182dup p.A728Gfs*82 | Frame Shift Ins (INS) | VAF 6/28 reads (21%) | catalogued as rs1463998365; called by mutect2, pindel
- NCOR1 | c.6751G>T p.G2251C | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.425); catalogued as COSV99251141; called by muse, mutect2, varscan2
- NCOR1 | c.1714C>T p.R572* | Nonsense Mutation (SNP) | VAF 45/222 reads (20%) | catalogued as COSV51982020; called by muse, mutect2, varscan2
- NES | c.1176del p.T393Hfs*9 | Frame Shift Del (DEL) | VAF 47/213 reads (22%) | catalogued as rs759081520; called by mutect2, pindel, varscan2
- NFATC2 | c.887C>A p.P296H | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.472); catalogued as rs759670807, COSV101044382; called by muse, mutect2, varscan2
- NLRP8 | c.619G>A p.A207T | Missense Mutation (SNP) | VAF 46/120 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV99405670; called by muse, mutect2, varscan2
- NOS1AP | c.140G>A p.S47N | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.95); catalogued as rs757647988, COSV100723495; called by muse, mutect2, varscan2
- NT5DC2 | c.1054del p.R352Afs*47 | Frame Shift Del (DEL) | VAF 10/36 reads (28%) | catalogued as COSV58740933; called by mutect2, pindel, varscan2
- NUDC | c.622C>T p.R208W | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.85); catalogued as rs537966346, COSV100345648; called by muse, mutect2, varscan2
- NUMA1 | c.4554G>T p.K1518N | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV100706415; called by muse, mutect2, varscan2
- ODC1 | c.1304G>A p.S435N | Missense Mutation (SNP) | VAF 18/132 reads (14%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV99301347; called by muse, mutect2, varscan2
- OLFM2 | c.700G>T p.D234Y | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99321918; called by muse, mutect2, varscan2
- OLFML1 | c.1084C>T p.P362S | Missense Mutation (SNP) | VAF 53/148 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1477099269, COSV100206754; called by muse, mutect2, varscan2
- OPTC | c.287C>T p.T96M | Missense Mutation (SNP) | VAF 38/93 reads (41%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs779076203, COSV65867382; called by muse, mutect2, varscan2
- OR10G2 | c.761C>T p.T254I | Missense Mutation (SNP) | VAF 42/91 reads (46%) | SIFT tolerated (0.25); PolyPhen probably damaging (1); catalogued as rs1406251635, COSV101606966; called by muse, mutect2, varscan2
- OR2T11 | c.880G>A p.V294I | Missense Mutation (SNP) | VAF 77/181 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as rs757689101, COSV100424897; called by muse, mutect2, varscan2
- OR2W3 | c.322G>T p.G108C | Missense Mutation (SNP) | VAF 48/127 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.557); catalogued as COSV100831763; called by muse, mutect2, varscan2
- OTUD7A | c.1643G>A p.G548D (on ENST00000307050 / NM_001382637.1; = p.G541D on NM_130901.3) | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100192877; called by muse, mutect2, varscan2
- PAMR1 | c.302del p.G101Vfs*8 | Frame Shift Del (DEL) | VAF 62/392 reads (16%) | catalogued as rs751755759; called by mutect2, varscan2
- PAPSS1 | c.1361T>C p.L454P | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99492253; called by muse, mutect2, varscan2
- PARD3B | c.304G>T p.D102Y | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100594514; called by muse, mutect2, varscan2
- PARP10 | c.292C>T p.P98S | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.037); catalogued as COSV100478176; called by muse, mutect2, varscan2
- PCDH15 | c.5717dup p.N1906Kfs*26 | Frame Shift Ins (INS) | VAF 45/135 reads (33%) | catalogued as rs778380770; called by mutect2, varscan2
- PCDHB4 | c.1588G>A p.V530M | Missense Mutation (SNP) | VAF 87/107 reads (81%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as COSV52022492; called by muse, mutect2, varscan2
- PCSK1 | c.887G>T p.R296I | Missense Mutation (SNP) | VAF 37/94 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768934109, COSV100227206; called by muse, mutect2, varscan2
- PDIA5 | c.673C>T p.R225C | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as rs772836826, COSV100299605; called by muse, mutect2, varscan2
- PHTF1 | c.2075dup p.P693Afs*3 | Frame Shift Ins (INS) | VAF 10/36 reads (28%) | catalogued as rs752176716; called by mutect2, varscan2
- PIK3R1 | c.1072C>T p.R358* (on ENST00000521381 / NM_181523.3; = p.R88* on NM_181504.4) | Nonsense Mutation (SNP) | VAF 48/54 reads (89%) | catalogued as COSV57123913; called by muse, mutect2, varscan2
- PIK3R4 | c.2014C>T p.R672C | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.057); catalogued as rs375991665; called by muse, mutect2, varscan2
- PKHD1L1 | c.6563del p.G2188Efs*28 | Frame Shift Del (DEL) | VAF 16/45 reads (36%) | catalogued as rs772426616; called by mutect2, pindel, varscan2
- PLAGL1 | c.443C>T p.P148L | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.024); catalogued as rs748313279, COSV99394611; called by muse, mutect2, varscan2
- PLEC | c.1370A>G p.Q457R (on ENST00000322810 / NM_201380.4; = p.Q347R on NM_000445.5) | Missense Mutation (SNP) | VAF 26/164 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100516718; called by muse, mutect2, varscan2
- PLPP4 | c.88G>C p.V30L | Missense Mutation (SNP) | VAF 57/70 reads (81%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as COSV100956459; called by muse, mutect2, varscan2
- PLSCR2 | c.232C>T p.P78S (on ENST00000497985 / NM_001199978.1; = p.P5S on NM_020359.2) | Missense Mutation (SNP) | VAF 28/100 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.169); catalogued as COSV100367831, COSV60862356; called by muse, mutect2, varscan2
- PLXNA3 | c.2441G>A p.C814Y | Missense Mutation (SNP) | VAF 27/53 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.731); catalogued as COSV100860124; called by muse, mutect2, varscan2
- PNPLA6 | c.886C>A p.L296M (on ENST00000414982 / NM_001166111.2; = p.L248M on NM_006702.5) | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as COSV99654150; called by muse, mutect2
- PNPLA7 | c.1418G>A p.G473D | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.3); PolyPhen benign (0.045); catalogued as rs775000584, COSV99479817, COSV99480318; called by muse, mutect2, varscan2
- POLG | c.898G>A p.A300T | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as COSV99174942; called by muse, mutect2, varscan2
- POM121 | c.3293C>T p.T1098M (on ENST00000434423; = p.T833M on NM_172020.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.093); catalogued as rs1451017061, COSV99988826; called by muse, mutect2, varscan2
- POU3F2 | c.976C>T p.P326S | Missense Mutation (SNP) | VAF 42/234 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60409371; called by muse, mutect2, varscan2
- PPP1R16B | c.341A>T p.E114V | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT tolerated (0.29); PolyPhen benign (0.348); catalogued as COSV100239779; called by muse, mutect2, varscan2
- PRG4 | c.1273A>C p.T425P | Missense Mutation (SNP) | VAF 24/154 reads (16%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV100798271; called by muse, varscan2
- PRKDC | c.8041G>A p.A2681T | Missense Mutation (SNP) | VAF 71/345 reads (21%) | SIFT tolerated (0.8); PolyPhen benign (0.003); catalogued as COSV100041810, COSV58067135; called by muse, mutect2, varscan2
- PRLHR | c.257C>T p.A86V | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT tolerated (0.3); PolyPhen benign (0.089); catalogued as rs775596574, COSV53302788; called by muse, mutect2, varscan2
- PRMT2 | c.705G>T p.K235N | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV99388768; called by muse, mutect2, varscan2
- PRPF40B | c.360G>A p.W120* (on ENST00000380281; = p.W114* on NM_012272.3) | Nonsense Mutation (SNP) | VAF 6/26 reads (23%) | catalogued as COSV99980021; called by muse, mutect2
- PRRX1 | c.386G>A p.R129H | Missense Mutation (SNP) | VAF 36/85 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as rs780981143, CM143961, COSV53411170; called by muse, mutect2, varscan2
- PSD | c.1083_1085del p.E361del | In Frame Del (DEL) | VAF 32/45 reads (71%) | catalogued as rs749446383; called by pindel, varscan2
- PSME2 | c.166G>C p.D56H | Missense Mutation (SNP) | VAF 20/102 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.376); catalogued as COSV99395674; called by muse, mutect2, varscan2
- PYGM | c.1283G>A p.R428H | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.022); catalogued as rs767293977, COSV99377392; called by mutect2, varscan2
- QKI | c.724C>T p.R242C | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.018); catalogued as COSV99275653; called by muse, mutect2, varscan2
- R3HDM2 | c.2734G>T p.G912W | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV100234662; called by muse, mutect2, varscan2
- RAB11FIP4 | c.784C>T p.R262W | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as rs759600561, COSV57926072; called by muse, mutect2, varscan2
- RAD54L | c.1535G>A p.S512N | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.063); catalogued as COSV100586486; called by muse, mutect2, varscan2
- RAD9A | c.349+2T>C p.X117_splice | Splice Site (SNP) | VAF 39/59 reads (66%) | catalogued as COSV100335012; called by muse, mutect2, varscan2
- RAPGEF1 | c.804del p.K269Sfs*38 | Frame Shift Del (DEL) | VAF 17/64 reads (27%) | catalogued as rs1564570119; called by mutect2, pindel, varscan2
- RBM15 | c.1922A>T p.K641M | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV100873476; called by muse, mutect2, varscan2
- RBM27 | c.2448del p.K816Nfs*5 | Frame Shift Del (DEL) | VAF 15/76 reads (20%) | catalogued as rs762006287; called by mutect2, varscan2
- RBM6 | c.2502dup p.P835Tfs*9 | Frame Shift Ins (INS) | VAF 38/51 reads (75%) | catalogued as rs775573264; called by mutect2, varscan2
- RBPJ | c.653del p.G218Efs*45 | Frame Shift Del (DEL) | VAF 86/149 reads (58%) | catalogued as COSV60753236; called by mutect2, pindel, varscan2
- RCE1 | c.925G>A p.G309S | Missense Mutation (SNP) | VAF 32/134 reads (24%) | SIFT tolerated (0.33); PolyPhen benign (0.006); catalogued as rs758150912, COSV100547145; called by muse, mutect2, varscan2
- RIPK2 | c.1006C>T p.P336S | Missense Mutation (SNP) | VAF 20/115 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV99610040; called by muse, mutect2, varscan2
- RNF17 | c.202A>G p.T68A | Missense Mutation (SNP) | VAF 59/109 reads (54%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.084); catalogued as COSV99693911; called by muse, mutect2, varscan2
- RP1L1 | c.851del p.P284Rfs*26 | Frame Shift Del (DEL) | VAF 28/99 reads (28%) | catalogued as rs757272743; called by mutect2, varscan2
- RTKN2 | c.347C>T p.S116F | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100189526; called by mutect2, varscan2
- RYR2 | c.2092G>A p.A698T | Missense Mutation (SNP) | VAF 22/109 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1215473213, COSV100772034; called by muse, mutect2, varscan2
- SAMD4B | c.1547A>G p.Q516R | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.081); catalogued as COSV100080518; called by muse, mutect2, varscan2
- SCRIB | c.1723G>A p.A575T | Missense Mutation (SNP) | VAF 39/112 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs752702092, COSV100253786; called by muse, mutect2, varscan2
- SEMA3G | c.727G>A p.V243M | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.877); catalogued as COSV99202522; called by muse, mutect2, varscan2
- SERINC1 | c.201+1G>T p.X67_splice | Splice Site (SNP) | VAF 24/129 reads (19%) | catalogued as rs768125967, COSV100305315; called by muse, varscan2
- SETX | c.797T>A p.F266Y | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99810397; called by muse, mutect2, varscan2
- SFMBT1 | c.2012G>A p.R671Q | Missense Mutation (SNP) | VAF 43/66 reads (65%) | SIFT deleterious (0); PolyPhen benign (0.421); catalogued as rs781621064, COSV99966144; called by muse, mutect2, varscan2
- SH3BGRL2 | c.249del p.F83Lfs*13 | Frame Shift Del (DEL) | VAF 62/180 reads (34%) | catalogued as COSV63965661; called by mutect2, pindel, varscan2
- SHC3 | c.751C>T p.R251W | Missense Mutation (SNP) | VAF 32/41 reads (78%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); catalogued as rs772738710, COSV65438244; called by muse, mutect2, varscan2
- SHH | c.1283C>T p.A428V | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0.038); catalogued as COSV99793478; called by muse, mutect2, varscan2
- SLBP | c.361A>G p.M121V | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs201877572; called by muse, mutect2, varscan2
- SLC13A5 | c.360G>T p.K120N | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.9); catalogued as rs796185984, COSV53422016; called by muse, mutect2
- SLC22A25 | c.187G>T p.D63Y | Missense Mutation (SNP) | VAF 38/114 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.635); catalogued as COSV100123802; called by muse, mutect2, varscan2
- SLC22A6 | c.1142C>T p.A381V | Missense Mutation (SNP) | VAF 39/72 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100842878; called by muse, mutect2, varscan2
- SLC30A8 | c.554C>T p.A185V | Missense Mutation (SNP) | VAF 10/198 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV101438661; called by muse, mutect2
- SLC34A1 | c.1520G>A p.R507H | Missense Mutation (SNP) | VAF 36/80 reads (45%) | SIFT tolerated (0.54); PolyPhen benign (0.006); catalogued as rs200137299; called by muse, mutect2, varscan2
- SLC34A2 | c.647G>T p.G216V | Missense Mutation (SNP) | VAF 63/86 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101158434; called by muse, mutect2, varscan2
- SLC44A4 | c.431dup p.N144Kfs*55 | Frame Shift Ins (INS) | VAF 19/98 reads (19%) | catalogued as rs764603659; called by mutect2, pindel, varscan2
- SLCO3A1 | c.1955A>G p.Y652C | Missense Mutation (SNP) | VAF 33/74 reads (45%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.827); catalogued as rs760179294, COSV100575724; called by muse, mutect2, varscan2
- SLPI | c.306del p.N103Ifs*13 | Frame Shift Del (DEL) | VAF 27/172 reads (16%) | catalogued as rs745834619; called by mutect2, varscan2
- SMC4 | c.3280G>A p.A1094T | Missense Mutation (SNP) | VAF 41/65 reads (63%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.588); catalogued as rs11548868, COSV59089168; called by muse, mutect2, varscan2
- SORBS1 | c.1633G>A p.V545I (on ENST00000361941 / NM_001034954.2; = p.V335I on NM_006434.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/49 reads (86%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.012); catalogued as rs534703247, COSV99528570; called by muse, mutect2, varscan2
- SORBS3 | c.1967G>T p.R656M | Missense Mutation (SNP) | VAF 70/270 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV53553073; called by muse, mutect2, varscan2
- SPECC1 | c.2245G>A p.V749M | Missense Mutation (SNP) | VAF 43/99 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.928); catalogued as rs757565254, COSV99822462; called by muse, mutect2, varscan2
- SPINT2 | c.520C>T p.R174C | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.553); catalogued as rs754350392, COSV100007516, COSV56649053; called by muse, mutect2, varscan2
- SPTLC3 | c.610A>G p.T204A | Missense Mutation (SNP) | VAF 47/236 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.297); catalogued as COSV100983235; called by muse, mutect2, varscan2
- SRARP | c.197C>A p.A66D | Missense Mutation (SNP) | VAF 106/201 reads (53%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.648); catalogued as COSV100272998, COSV61497925; called by muse, mutect2, varscan2
- SRCAP | c.1825C>T p.P609S | Missense Mutation (SNP) | VAF 10/182 reads (5%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.922); catalogued as COSV99350801; called by muse, mutect2
- STC2 | c.549G>T p.E183D | Missense Mutation (SNP) | VAF 25/29 reads (86%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.52); catalogued as COSV99438554; called by muse, mutect2, varscan2
- STRC | c.461del p.P154Lfs*30 | Frame Shift Del (DEL) | VAF 37/118 reads (31%) | catalogued as rs1411667337; called by mutect2, varscan2
- SULT1C4 | c.13G>A p.D5N | Missense Mutation (SNP) | VAF 112/243 reads (46%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as rs923195067, COSV55597073; called by muse, mutect2, varscan2
- SUN3 | c.122G>T p.G41V | Missense Mutation (SNP) | VAF 24/138 reads (17%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.278); catalogued as COSV99814246; called by muse, mutect2, varscan2
- SUPT16H | c.1174A>G p.K392E | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT tolerated (0.36); PolyPhen benign (0.026); catalogued as rs779648070, COSV53522481, COSV53522493; called by muse, mutect2, varscan2
- SUZ12 | c.1404A>T p.K468N | Missense Mutation (SNP) | VAF 32/197 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.614); catalogued as COSV100496987; called by muse, mutect2, varscan2
- SYNPO2 | c.862C>A p.L288I | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as COSV100206103; called by muse, mutect2, varscan2
- SYT12 | c.531G>T p.K177N | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.636); catalogued as COSV101210961; called by mutect2, varscan2
- TBC1D23 | c.1660A>G p.I554V (on ENST00000394144 / NM_001199198.3; = p.I539V on NM_018309.5) | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV100792695; called by muse, mutect2, varscan2
- TBX4 | c.246G>T p.E82D | Missense Mutation (SNP) | VAF 10/99 reads (10%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.642); catalogued as COSV99540494; called by muse, mutect2, varscan2
- TCOF1 | c.1787C>T p.A596V (on ENST00000377797 / NM_001135243.1; = p.A519V on NM_000356.4) | Missense Mutation (SNP) | VAF 38/94 reads (40%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.9); catalogued as COSV100077905; called by muse, mutect2, varscan2
- TCTEX1D1 | c.232G>A p.V78M | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.089); catalogued as COSV99259299; called by muse, mutect2, varscan2
- TENM3 | c.6718A>G p.T2240A | Missense Mutation (SNP) | VAF 4/51 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.027); catalogued as COSV101305296; called by muse, mutect2
- TENT4A | c.805G>A p.E269K | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.249); catalogued as rs766876723, COSV50095100, COSV50095698; called by muse, mutect2, varscan2
- TGFBRAP1 | c.1319T>C p.V440A | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV51512085; called by muse, mutect2, varscan2
- TINF2 | c.908C>A p.P303H | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.479); catalogued as COSV99945633; called by muse, mutect2
- TLNRD1 | c.914G>A p.C305Y | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.31); PolyPhen benign (0.103); catalogued as COSV99146138; called by muse, mutect2, varscan2
- TMEM79 | c.1112C>T p.A371V | Missense Mutation (SNP) | VAF 12/202 reads (6%) | SIFT tolerated (0.69); PolyPhen benign (0.225); catalogued as rs1368596458, COSV99828028; called by muse, mutect2
- TNPO3 | c.890G>A p.R297H | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.179); catalogued as rs1322479758, COSV55288133; called by muse, mutect2, varscan2
- TPM2 | c.46G>C p.E16Q | Missense Mutation (SNP) | VAF 147/207 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100253399, COSV61405171; called by muse, mutect2, varscan2
- TRIO | c.6092del p.L2031* | Frame Shift Del (DEL) | VAF 15/75 reads (20%) | catalogued as rs752676391; called by mutect2, varscan2
- TRMT9B | c.742C>A p.R248S | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV101501634; called by muse, mutect2, varscan2
- TRPC3 | c.386G>A p.R129H (on ENST00000379645 / NM_001366479.2; = p.R56H on NM_003305.2) | Missense Mutation (SNP) | VAF 41/62 reads (66%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs775346133, COSV53378201; called by muse, mutect2, varscan2
- TRPM4 | c.709G>T p.D237Y | Missense Mutation (SNP) | VAF 22/40 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99420515; called by muse, varscan2
- TRPV4 | c.1423G>A p.V475M | Missense Mutation (SNP) | VAF 52/123 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.974); catalogued as COSV55681064, COSV99924748; called by muse, mutect2, varscan2
- TSPAN8 | c.615T>A p.N205K | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.14); catalogued as rs139952436, COSV99922643; called by muse, mutect2, varscan2
- TTN | c.12563A>G p.E4188G (on ENST00000591111; = p.E4142G on NM_003319.4) | Missense Mutation (SNP) | VAF 123/261 reads (47%) | catalogued as rs376924571; called by muse, mutect2, varscan2
- TUBE1 | c.881C>T p.P294L | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.944); catalogued as COSV64087853; called by muse, mutect2, varscan2
- UBA3 | c.1048G>A p.G350R | Missense Mutation (SNP) | VAF 125/165 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100734740; called by muse, mutect2, varscan2
- UBOX5 | c.1612C>T p.R538W | Missense Mutation (SNP) | VAF 8/156 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs950917852, COSV99418347; called by muse, mutect2
- UNC13D | c.787del p.L263Wfs*65 | Frame Shift Del (DEL) | VAF 7/54 reads (13%) | catalogued as COSV99255986; called by mutect2, pindel, varscan2
- UPF1 | c.1126C>T p.R376W (on ENST00000599848 / NM_001297549.2; = p.R365W on NM_002911.4) | Missense Mutation (SNP) | VAF 20/102 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.038); catalogued as rs746623373, COSV99440087; called by muse, mutect2, varscan2
- USP24 | c.7085G>A p.G2362D | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.037); catalogued as COSV99600434; called by muse, mutect2, varscan2
- USP24 | c.2189G>A p.R730H | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.337); catalogued as rs1261033412, COSV53763139; called by muse, mutect2, varscan2
- USP36 | c.3235G>A p.G1079R | Missense Mutation (SNP) | VAF 52/304 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100361681; called by muse, mutect2, varscan2
- USP4 | c.1558G>A p.E520K | Missense Mutation (SNP) | VAF 88/127 reads (69%) | SIFT tolerated (0.88); PolyPhen benign (0.017); catalogued as rs746574786, COSV55539926, COSV99649924; called by muse, mutect2, varscan2
- USP47 | c.2881A>G p.I961V (on ENST00000399455 / NM_001372095.1; = p.I873V on NM_017944.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/162 reads (6%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.558); catalogued as COSV100359804; called by muse, mutect2
- USP6 | c.3745C>T p.R1249W | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.917); catalogued as rs766078594, COSV51494019; called by muse, mutect2, varscan2
- VPS13C | c.7949A>G p.Y2650C (on ENST00000644861 / NM_020821.3; = p.Y2607C on NM_017684.5) | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV99829458; called by muse, mutect2, varscan2
- VPS13D | c.9289C>T p.R3097W | Missense Mutation (SNP) | VAF 72/169 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs758689804, COSV99167730; called by muse, mutect2, varscan2
- WDFY1 | c.233A>G p.H78R | Missense Mutation (SNP) | VAF 8/113 reads (7%) | SIFT tolerated (0.4); PolyPhen benign (0.115); catalogued as COSV99239701; called by muse, mutect2
- WDR70 | c.622T>G p.F208V | Missense Mutation (SNP) | VAF 35/132 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV99459563; called by muse, mutect2, varscan2
- WNT16 | c.910G>T p.G304W (on ENST00000222462 / NM_057168.2; = p.G294W on NM_016087.2) | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99743292; called by muse, mutect2
- WNT9A | c.791C>T p.A264V | Missense Mutation (SNP) | VAF 29/109 reads (27%) | SIFT tolerated (0.26); PolyPhen benign (0.34); catalogued as COSV99688355; called by muse, mutect2, varscan2
- YIF1A | c.391del p.R131Gfs*50 | Frame Shift Del (DEL) | VAF 5/33 reads (15%) | catalogued as rs761507279; called by mutect2, pindel, varscan2
- YLPM1 | c.4069C>T p.R1357* | Nonsense Mutation (SNP) | VAF 20/221 reads (9%) | catalogued as rs1358992706, COSV53108618; called by muse, mutect2
- ZC3H13 | c.4078G>C p.E1360Q | Missense Mutation (SNP) | VAF 26/28 reads (93%) | SIFT tolerated, low confidence (0.17); PolyPhen probably damaging (0.994); catalogued as COSV99668585; called by muse, mutect2, varscan2
- ZCCHC24 | c.262G>A p.V88M | Missense Mutation (SNP) | VAF 20/25 reads (80%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.021); catalogued as rs761788598, COSV100959448; called by muse, mutect2, varscan2
- ZFP69B | c.305T>C p.V102A | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.446); catalogued as COSV100848281; called by muse, varscan2
- ZNF175 | c.1789A>G p.N597D | Missense Mutation (SNP) | VAF 28/199 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.382); catalogued as COSV99219647; called by muse, mutect2, varscan2
- ZNF223 | c.1346dup p.N449Kfs*11 | Frame Shift Ins (INS) | VAF 37/152 reads (24%) | catalogued as rs758726370; called by mutect2, varscan2
- ZNF267 | c.1440_1442del p.I480del | In Frame Del (DEL) | VAF 54/109 reads (50%) | catalogued as rs746782142; called by pindel, varscan2
- ZNF284 | c.1204G>A p.D402N | Missense Mutation (SNP) | VAF 17/188 reads (9%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.764); catalogued as rs549267532, COSV101399040; called by muse, mutect2
- ZNF33A | c.206A>G p.E69G | Missense Mutation (SNP) | VAF 47/328 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.612); catalogued as COSV100276060; called by muse, mutect2, varscan2
- ZNF432 | c.611del p.N204Tfs*45 | Frame Shift Del (DEL) | VAF 75/222 reads (34%) | catalogued as rs1438216527; called by mutect2, pindel, varscan2
- ZNF480 | c.1156C>A p.L386I | Missense Mutation (SNP) | VAF 21/104 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs775434873, COSV100574277; called by muse, mutect2, varscan2
- ZNF492 | c.182dup p.N61Kfs*12 | Frame Shift Ins (INS) | VAF 16/28 reads (57%) | catalogued as rs754633801; called by mutect2, varscan2
- ZNF548 | c.805A>G p.M269V | Missense Mutation (SNP) | VAF 39/87 reads (45%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as COSV100278239; called by muse, mutect2, varscan2
- ZNF676 | c.1160A>G p.H387R (on ENST00000650058; = p.H355R on NM_001001411.3) | Missense Mutation (SNP) | VAF 60/190 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1169458947, COSV101236287; called by muse, varscan2
- ZNF808 | c.2237A>G p.Q746R | Missense Mutation (SNP) | VAF 32/305 reads (10%) | SIFT tolerated (0.66); PolyPhen benign (0.007); catalogued as rs1568491990, COSV100708100; called by muse, mutect2, varscan2
- ZRANB2 | c.602G>A p.R201Q | Missense Mutation (SNP) | VAF 66/117 reads (56%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs772508465, COSV54672313; called by muse, mutect2, varscan2
- AFF3 | c.3325del p.A1109Pfs*155 | Frame Shift Del (DEL) | VAF 8/84 reads (10%) | called by mutect2, pindel, varscan2
- AKAP8 | c.790dup p.A264Gfs*5 | Frame Shift Ins (INS) | VAF 6/24 reads (25%) | called by mutect2, pindel, varscan2
- ALG1 | c.398del p.P133Qfs*59 | Frame Shift Del (DEL) | VAF 30/265 reads (11%) | called by mutect2, varscan2
- AMOTL1 | c.1000dup p.Y334Lfs*3 | Frame Shift Ins (INS) | VAF 36/161 reads (22%) | called by mutect2, pindel, varscan2
- ANKAR | c.1804dup p.R602Kfs*13 | Frame Shift Ins (INS) | VAF 40/204 reads (20%) | called by mutect2, varscan2
- ATP1B2 | c.142dup p.Y48Lfs*42 | Frame Shift Ins (INS) | VAF 14/156 reads (9%) | called by mutect2, pindel
- AVPR1B | c.418del p.L140Cfs*38 | Frame Shift Del (DEL) | VAF 10/99 reads (10%) | called by mutect2, pindel, varscan2
- BCL9 | c.2697_2699del p.A903del | In Frame Del (DEL) | VAF 18/95 reads (19%) | called by mutect2, pindel, varscan2
- BEND3 | c.2448del p.K816Nfs*17 | Frame Shift Del (DEL) | VAF 52/138 reads (38%) | called by mutect2, pindel, varscan2
- BICRAL | c.2689dup p.T897Nfs*11 | Frame Shift Ins (INS) | VAF 10/66 reads (15%) | called by mutect2, varscan2
- BTG3 | c.1del p.M1? | Frame Shift Del (DEL) | VAF 52/118 reads (44%) | called by mutect2, varscan2
- BUB1 | c.1727del p.L576Wfs*47 | Frame Shift Del (DEL) | VAF 53/283 reads (19%) | called by mutect2, pindel, varscan2
- CBLL1 | c.1259del p.P420Lfs*20 | Frame Shift Del (DEL) | VAF 32/117 reads (27%) | called by mutect2, pindel, varscan2
- CELSR3 | c.420_422del p.S141del | In Frame Del (DEL) | VAF 59/97 reads (61%) | called by pindel, varscan2
- CNTRL | c.4194_4195del p.L1401Yfs*3 | Frame Shift Del (DEL) | VAF 22/35 reads (63%) | called by mutect2, pindel, varscan2
- CYB5R2 | c.272dup p.N91Kfs*8 | Frame Shift Ins (INS) | VAF 22/175 reads (13%) | called by mutect2, pindel, varscan2
- DDX10 | c.2028del p.V677* | Frame Shift Del (DEL) | VAF 48/168 reads (29%) | called by mutect2, varscan2
- DHCR7 | c.964-3del | Splice Region (DEL) | VAF 14/32 reads (44%) | called by mutect2, pindel
- DUSP14 | c.318del p.T107Pfs*9 | Frame Shift Del (DEL) | VAF 32/94 reads (34%) | called by mutect2, pindel, varscan2
- ECSIT | c.900_901del p.Y301Lfs*7 | Frame Shift Del (DEL) | VAF 16/92 reads (17%) | called by pindel, varscan2
- ERMN | c.391_393del p.K131del | In Frame Del (DEL) | VAF 22/97 reads (23%) | called by mutect2, pindel, varscan2
- EXOC6B | c.1053dup p.V352Cfs*3 | Frame Shift Ins (INS) | VAF 12/89 reads (13%) | called by mutect2, pindel, varscan2
- FAM133A | c.157dup p.T53Nfs*8 | Frame Shift Ins (INS) | VAF 13/27 reads (48%) | called by mutect2, varscan2
- FBXO46 | c.872del p.P291Lfs*80 | Frame Shift Del (DEL) | VAF 25/65 reads (38%) | called by mutect2, pindel, varscan2
- FCGBP | c.7814C>G p.P2605R | Missense Mutation (SNP) | VAF 34/418 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.664); called by muse, mutect2
- GOPC | c.1380del p.K460Nfs*27 | Frame Shift Del (DEL) | VAF 35/167 reads (21%) | called by pindel, varscan2
- GPR89B | c.54del p.F18Lfs*25 | Frame Shift Del (DEL) | VAF 42/188 reads (22%) | called by mutect2, varscan2
- GRHL1 | c.732dup p.D245* | Frame Shift Ins (INS) | VAF 10/46 reads (22%) | called by mutect2, pindel, varscan2
- GTF2IRD2B | c.2234G>A p.S745N | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.932); called by mutect2, varscan2
- IFT88 | c.1358del p.K453Rfs*5 (on ENST00000319980 / NM_001318493.2; = p.K444Rfs*5 on NM_006531.5 and 9 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 100/157 reads (64%) | called by mutect2, pindel, varscan2
- ITGB1 | c.1313del p.K438Rfs*17 | Frame Shift Del (DEL) | VAF 72/328 reads (22%) | called by mutect2, pindel, varscan2
- KDM7A | c.289del p.R97Gfs*41 | Frame Shift Del (DEL) | VAF 18/92 reads (20%) | called by mutect2, pindel, varscan2
- KLHDC7B | c.1478dup p.F494Lfs*94 (on ENST00000395676; = p.F1135Lfs*94 on NM_138433.5) | Frame Shift Ins (INS) | VAF 20/106 reads (19%) | called by mutect2, pindel, varscan2
- KMT2D | c.9265del p.V3089Wfs*30 | Frame Shift Del (DEL) | VAF 23/52 reads (44%) | called by mutect2, varscan2
- LACC1 | c.56dup p.N19Kfs*31 | Frame Shift Ins (INS) | VAF 16/71 reads (23%) | called by mutect2, varscan2
- LRP1B | c.7058dup p.N2353Kfs*36 | Frame Shift Ins (INS) | VAF 23/123 reads (19%) | called by mutect2, pindel, varscan2
- MPRIP | c.1058del p.P353Qfs*30 | Frame Shift Del (DEL) | VAF 14/38 reads (37%) | called by mutect2, pindel
- MRPL30 | c.115_116del p.S39Kfs*12 | Frame Shift Del (DEL) | VAF 10/43 reads (23%) | called by mutect2, pindel, varscan2
- MUC5AC | c.13808del p.P4603Lfs*82 | Frame Shift Del (DEL) | VAF 28/201 reads (14%) | called by mutect2, pindel, varscan2
- NMRK2 | c.600del p.S201Pfs*64 | Frame Shift Del (DEL) | VAF 35/81 reads (43%) | called by mutect2, pindel, varscan2
- NSD1 | c.5508dup p.A1837Sfs*10 | Frame Shift Ins (INS) | VAF 29/56 reads (52%) | called by mutect2, pindel, varscan2
- OR6V1 | c.116dup p.N40Kfs*11 | Frame Shift Ins (INS) | VAF 50/226 reads (22%) | called by mutect2, pindel, varscan2
- OR8B4 | c.753dup p.G252Wfs*34 | Frame Shift Ins (INS) | VAF 26/46 reads (57%) | called by mutect2, pindel, varscan2
- PLCH1 | c.622dup p.Y208Lfs*19 (on ENST00000340059 / NM_001130960.2; = p.Y220Lfs*19 on NM_014996.4 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 17/92 reads (18%) | called by mutect2, pindel, varscan2
- RPF2 | c.481del p.S161Vfs*20 | Frame Shift Del (DEL) | VAF 20/110 reads (18%) | called by mutect2, pindel, varscan2
- RPRD1B | c.411del p.A139Qfs*8 | Frame Shift Del (DEL) | VAF 16/135 reads (12%) | called by mutect2, pindel, varscan2
- RPS6KB1 | c.41del p.P14Rfs*17 | Frame Shift Del (DEL) | VAF 8/25 reads (32%) | called by mutect2, pindel, varscan2
- RSBN1 | c.1679del p.N560Ifs*42 | Frame Shift Del (DEL) | VAF 54/113 reads (48%) | called by mutect2, pindel, varscan2
- RTTN | c.410del p.N137Tfs*5 | Frame Shift Del (DEL) | VAF 9/50 reads (18%) | called by mutect2, pindel, varscan2
- SAXO2 | c.222del p.G75Efs*35 | Frame Shift Del (DEL) | VAF 21/97 reads (22%) | called by mutect2, pindel, varscan2
- SGCA | c.284dup p.E96Rfs*9 | Frame Shift Ins (INS) | VAF 11/37 reads (30%) | called by mutect2, pindel, varscan2
- SH3GL2 | c.757dup p.R253Kfs*6 | Frame Shift Ins (INS) | VAF 22/59 reads (37%) | called by mutect2, pindel, varscan2
- SLC39A6 | c.91del p.Q31Rfs*52 | Frame Shift Del (DEL) | VAF 24/114 reads (21%) | called by mutect2, pindel, varscan2
- SPEG | c.996del p.T333Rfs*45 | Frame Shift Del (DEL) | VAF 7/21 reads (33%) | called by mutect2, varscan2
- SSH3 | c.1460dup p.H488Afs*5 | Frame Shift Ins (INS) | VAF 33/102 reads (32%) | called by mutect2, pindel, varscan2
- ST3GAL3 | c.936+1del | Frame Shift Del (DEL) | VAF 17/76 reads (22%) | called by mutect2, varscan2
- STARD13 | c.2889del p.S964Qfs*4 (on ENST00000336934 / NM_001243476.3; = p.S846Qfs*4 on NM_052851.3) | Frame Shift Del (DEL) | VAF 57/93 reads (61%) | called by mutect2, pindel, varscan2
- SZT2 | c.2175del p.V726Cfs*41 | Frame Shift Del (DEL) | VAF 8/34 reads (24%) | called by mutect2, pindel, varscan2
- TDRD5 | c.1907del p.L636Cfs*16 | Frame Shift Del (DEL) | VAF 72/170 reads (42%) | called by mutect2, varscan2
- TGFBR3 | c.428_430del p.S143del | In Frame Del (DEL) | VAF 79/165 reads (48%) | called by mutect2, pindel, varscan2
- TMEM131 | c.4833del p.C1612Afs*23 | Frame Shift Del (DEL) | VAF 7/32 reads (22%) | called by mutect2, pindel, varscan2
- TNFRSF6B | c.464del p.P155Qfs*101 | Frame Shift Del (DEL) | VAF 11/36 reads (31%) | called by mutect2, pindel, varscan2
- TSFM | c.417G>C p.Q139H | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.242); called by muse, mutect2
- UBQLN2 | c.1574del p.P525Lfs*71 | Frame Shift Del (DEL) | VAF 8/16 reads (50%) | called by mutect2, varscan2
- UNC13D | c.2065_2067del p.K689del | In Frame Del (DEL) | VAF 9/62 reads (15%) | called by mutect2, pindel, varscan2
- UNC13D | c.446dup p.S150Qfs*44 | Frame Shift Ins (INS) | VAF 10/100 reads (10%) | called by mutect2, pindel
- UNC45A | c.239_240del p.E80Gfs*6 | Frame Shift Del (DEL) | VAF 25/72 reads (35%) | called by pindel, varscan2
- USP54 | c.833dup p.R279Qfs*5 | Frame Shift Ins (INS) | VAF 26/66 reads (39%) | called by mutect2, pindel, varscan2
- ZBTB20 | c.2075del p.P692Lfs*43 (on ENST00000474710 / NM_001164342.2; = p.P619Lfs*43 on NM_015642.6 and 4 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 25/92 reads (27%) | called by mutect2, pindel, varscan2
- ZBTB7C | c.960del p.P321Lfs*18 | Frame Shift Del (DEL) | VAF 43/99 reads (43%) | called by mutect2, pindel, varscan2
- ZNF18 | c.1165_1167del p.E389del | In Frame Del (DEL) | VAF 58/152 reads (38%) | called by pindel, varscan2
- ZNF516 | c.2529del p.M844Cfs*131 | Frame Shift Del (DEL) | VAF 35/120 reads (29%) | called by mutect2, pindel, varscan2
- ACD | c.423G>T p.G141= (on ENST00000620338; = p.G52= on NM_022914.3) | Silent (SNP) | VAF 22/45 reads (49%) | catalogued as COSV99537892; called by muse, mutect2, varscan2
- ADGRD1 | c.963C>A p.T321= | Silent (SNP) | VAF 18/165 reads (11%) | catalogued as COSV99896370; called by muse, mutect2, varscan2
- ALPK2 | c.1098C>T p.F366= | Silent (SNP) | VAF 53/91 reads (58%) | catalogued as rs762606578, COSV64496753; called by muse, mutect2, varscan2
- ANKRD11 | c.6459G>A p.A2153= | Silent (SNP) | VAF 17/38 reads (45%) | catalogued as rs755422031, COSV99970123; called by muse, mutect2, varscan2
- ASAP2 | c.330A>G p.A110= | Silent (SNP) | VAF 27/95 reads (28%) | catalogued as COSV99856541; called by muse, mutect2, varscan2
- ATL2 | c.846G>A p.K282= | Silent (SNP) | VAF 14/84 reads (17%) | catalogued as rs746271599, COSV100184858; called by muse, mutect2, varscan2
- ATXN1 | c.1947T>C p.P649= | Silent (SNP) | VAF 24/124 reads (19%) | catalogued as COSV55211096, COSV99787090; called by muse, mutect2, varscan2
- BEST2 | c.165C>T p.T55= | Silent (SNP) | VAF 20/132 reads (15%) | catalogued as rs746848138, COSV99244559; called by muse, mutect2, varscan2
- BMP2K | c.3423C>A p.S1141= | Silent (SNP) | VAF 99/125 reads (79%) | catalogued as COSV55011253; called by muse, mutect2, varscan2
- BMPR1A | c.180G>A p.K60= | Silent (SNP) | VAF 92/119 reads (77%) | catalogued as COSV100776693; called by muse, varscan2
- C1QTNF4 | c.648G>A p.A216= | Silent (SNP) | VAF 26/44 reads (59%) | catalogued as COSV100209355; called by muse, mutect2, varscan2
- CAMTA2 | c.663T>G p.A221= | Silent (SNP) | VAF 14/172 reads (8%) | catalogued as COSV100772703; called by muse, mutect2
- CAND1 | c.2370T>C p.L790= | Silent (SNP) | VAF 46/190 reads (24%) | catalogued as COSV101607338; called by muse, mutect2, varscan2
- CASKIN1 | c.1893C>T p.I631= | Silent (SNP) | VAF 18/39 reads (46%) | catalogued as rs759641819, COSV100399707; called by muse, mutect2, varscan2
- CD44 | c.714G>A p.R238= | Silent (SNP) | VAF 16/107 reads (15%) | catalogued as COSV99555904; called by muse, mutect2, varscan2
- CDH13 | c.1321C>T p.L441= | Silent (SNP) | VAF 28/66 reads (42%) | catalogued as COSV99228457; called by muse, mutect2, varscan2
- CDH9 | c.2010A>G p.Q670= | Silent (SNP) | VAF 44/234 reads (19%) | catalogued as rs372708117; called by muse, mutect2, varscan2
- CEL | c.1557C>T p.S519= (on ENST00000673714; = p.S516= on NM_001807.6) | Silent (SNP) | VAF 9/33 reads (27%) | catalogued as rs750895913, COSV100672660; called by muse, mutect2, varscan2
- CENPE | c.6639G>A p.Q2213= | Silent (SNP) | VAF 32/45 reads (71%) | catalogued as rs1317177030, COSV99478596; called by muse, mutect2, varscan2
- COPA | c.3456C>T p.P1152= | Silent (SNP) | VAF 41/284 reads (14%) | catalogued as COSV99616336; called by muse, mutect2, varscan2
- CSTB | c.120C>A p.A40= | Silent (SNP) | VAF 22/102 reads (22%) | catalogued as COSV99376966; called by muse, mutect2, varscan2
- DCHS1 | c.7806T>C p.F2602= | Silent (SNP) | VAF 30/396 reads (8%) | catalogued as COSV100197616; called by muse, mutect2
- DCST1 | c.1965C>T p.P655= | Silent (SNP) | VAF 7/25 reads (28%) | catalogued as rs1228233395, COSV99665161; called by muse, mutect2, varscan2
- DIDO1 | c.2409G>A p.E803= | Silent (SNP) | VAF 34/190 reads (18%) | catalogued as COSV99826533; called by muse, mutect2, varscan2
- DNAH3 | c.8301C>T p.L2767= | Silent (SNP) | VAF 23/127 reads (18%) | catalogued as rs778809328, COSV99769222; called by muse, mutect2, varscan2
- EMILIN3 | c.189G>A p.V63= | Silent (SNP) | VAF 8/77 reads (10%) | catalogued as COSV100182701; called by muse, mutect2, varscan2
- FAM110B | c.411C>T p.H137= | Silent (SNP) | VAF 10/36 reads (28%) | catalogued as rs1177414144, COSV64067334; called by muse, mutect2, varscan2
- FAT3 | c.6537C>A p.V2179= | Silent (SNP) | VAF 10/51 reads (20%) | catalogued as COSV99968252; called by muse, mutect2, varscan2
- FMN2 | c.2814C>A p.P938= | Silent (SNP) | VAF 58/112 reads (52%) | catalogued as rs1183411950, COSV100148212; called by muse, mutect2, varscan2
- GDA | c.837C>T p.H279= | Silent (SNP) | VAF 13/34 reads (38%) | catalogued as rs748189548, COSV52991225; called by muse, mutect2, varscan2
- GPBAR1 | c.603G>A p.R201= | Silent (SNP) | VAF 14/42 reads (33%) | catalogued as COSV99946437; called by muse, mutect2
- HYAL4 | c.96C>T p.I32= | Silent (SNP) | VAF 37/126 reads (29%) | catalogued as COSV99772372; called by muse, mutect2, varscan2
- IGHV3-43 | c.51C>T p.V17= | Silent (SNP) | VAF 40/194 reads (21%) | catalogued as rs1295864916; called by muse, mutect2, varscan2
- IL16 | c.1293T>C p.G431= | Silent (SNP) | VAF 16/132 reads (12%) | catalogued as rs773265360, COSV100267876; called by muse, mutect2, varscan2
- IL17B | c.165G>A p.P55= | Silent (SNP) | VAF 58/76 reads (76%) | catalogued as rs376026730; called by muse, mutect2, varscan2
- ILF2 | c.12C>T p.D4= | Silent (SNP) | VAF 21/91 reads (23%) | catalogued as COSV100721978; called by muse, mutect2, varscan2
- ILF3 | c.588C>T p.D196= | Silent (SNP) | VAF 33/114 reads (29%) | catalogued as rs751279668, COSV99140007; called by muse, mutect2, varscan2
- INPP5D | c.3144G>A p.P1048= (on ENST00000445964 / NM_001017915.3; = p.P1047= on NM_005541.5) | Silent (SNP) | VAF 42/101 reads (42%) | catalogued as rs762287573, COSV100856867, COSV64037384; called by muse, mutect2, varscan2
- INTS8 | c.171G>A p.Q57= | Silent (SNP) | VAF 81/148 reads (55%) | catalogued as COSV100569371; called by muse, mutect2, varscan2
- KCNH4 | c.2280C>T p.S760= | Silent (SNP) | VAF 3/12 reads (25%) | catalogued as COSV99237637; called by muse, mutect2
- KCNQ5 | c.771A>G p.S257= | Silent (SNP) | VAF 36/74 reads (49%) | catalogued as rs778022470, COSV100572581; called by muse, mutect2, varscan2
- KRI1 | c.702T>C p.D234= | Silent (SNP) | VAF 12/180 reads (7%) | catalogued as COSV100470286; called by muse, mutect2
- KRI1 | c.342C>T p.Y114= | Silent (SNP) | VAF 48/199 reads (24%) | catalogued as COSV100224862; called by muse, mutect2, varscan2
- KRT6B | c.507C>T p.T169= | Silent (SNP) | VAF 29/287 reads (10%) | catalogued as COSV99360878; called by muse, mutect2, varscan2
- LAD1 | c.1329C>T p.H443= | Silent (SNP) | VAF 51/235 reads (22%) | catalogued as COSV100943897; called by muse, mutect2, varscan2
- LIMCH1 | c.1587T>C p.T529= | Silent (SNP) | VAF 47/115 reads (41%) | catalogued as COSV100574146; called by muse, mutect2, varscan2
- LRP2 | c.10704G>A p.P3568= | Silent (SNP) | VAF 10/103 reads (10%) | catalogued as rs756473581, COSV55565974; ClinVar: uncertain significance; called by muse, mutect2
- LRRC73 | c.444G>A p.E148= | Silent (SNP) | VAF 20/69 reads (29%) | catalogued as COSV99447133; called by muse, mutect2, varscan2
- MARCHF2 | c.327C>T p.C109= | Silent (SNP) | VAF 10/64 reads (16%) | catalogued as rs1213384303, COSV99294830; called by muse, mutect2, varscan2
- NAT16 | c.225C>T p.G75= | Silent (SNP) | VAF 27/71 reads (38%) | catalogued as COSV100296343; called by muse, mutect2, varscan2
- NEBL | c.981T>C p.H327= | Silent (SNP) | VAF 44/137 reads (32%) | catalogued as COSV101009289; called by muse, mutect2, varscan2
- NFKBIB | c.753C>A p.A251= | Silent (SNP) | VAF 61/139 reads (44%) | catalogued as COSV100548458; called by muse, mutect2, varscan2
- NPHP3 | c.585C>T p.S195= | Silent (SNP) | VAF 32/135 reads (24%) | catalogued as COSV100447148; called by muse, mutect2, varscan2
- NUFIP1 | c.267G>A p.A89= | Silent (SNP) | VAF 19/46 reads (41%) | catalogued as COSV63151538; called by muse, mutect2, varscan2
- OLFM1 | c.1041C>T p.Y347= (on ENST00000371793 / NM_001282611.2; = p.Y329= on NM_014279.5) | Silent (SNP) | VAF 37/44 reads (84%) | catalogued as rs138868145; called by muse, mutect2, varscan2
- OR51F2 | c.891G>A p.K297= | Silent (SNP) | VAF 130/237 reads (55%) | catalogued as COSV59063641, COSV59064885; called by muse, mutect2, varscan2
- OR5I1 | c.756C>A p.I252= | Silent (SNP) | VAF 23/40 reads (58%) | catalogued as COSV100041597, COSV56887698; called by muse, mutect2, varscan2
- OTOP3 | c.1656C>T p.I552= | Silent (SNP) | VAF 57/134 reads (43%) | catalogued as rs773928388, COSV100172741; called by muse, mutect2, varscan2
- PALB2 | c.768C>T p.S256= | Silent (SNP) | VAF 59/294 reads (20%) | catalogued as rs45487491, COSV55163528; ClinVar: likely benign; called by muse, mutect2, varscan2
- PAX4 | c.507C>T p.T169= | Silent (SNP) | VAF 47/82 reads (57%) | catalogued as rs766014675, COSV100490248; called by muse, mutect2, varscan2
- PCDH15 | c.2541C>T p.D847= | Silent (SNP) | VAF 90/124 reads (73%) | catalogued as COSV100224632; called by muse, mutect2, varscan2
- PCDHB3 | c.2379T>C p.F793= | Silent (SNP) | VAF 45/112 reads (40%) | catalogued as COSV99165911; called by muse, mutect2, varscan2
- PCDHB9 | c.2202G>A p.G734= | Silent (SNP) | VAF 53/152 reads (35%) | catalogued as rs782534419; called by muse, mutect2, varscan2
- PDE1A | c.939A>G p.K313= | Silent (SNP) | VAF 26/70 reads (37%) | catalogued as COSV100115440; called by muse, mutect2, varscan2
- PDGFRA | c.1284T>C p.T428= | Silent (SNP) | VAF 16/75 reads (21%) | catalogued as rs763716086, COSV99957221; called by muse, mutect2, varscan2
- PDIA4 | c.250C>T p.L84= | Silent (SNP) | VAF 10/36 reads (28%) | catalogued as COSV99618742; called by muse, mutect2, varscan2
- PIDD1 | c.156C>T p.H52= | Silent (SNP) | VAF 13/76 reads (17%) | catalogued as rs779847146, COSV100758720; called by muse, mutect2, varscan2
- PIK3C2A | c.3186A>G p.K1062= | Silent (SNP) | VAF 60/241 reads (25%) | catalogued as COSV99791024; called by muse, mutect2, varscan2
- PIK3R5 | c.1548G>A p.T516= | Silent (SNP) | VAF 30/139 reads (22%) | catalogued as rs780537367, COSV52651094; called by muse, mutect2, varscan2
- PIKFYVE | c.1884A>T p.S628= | Silent (SNP) | VAF 49/132 reads (37%) | catalogued as COSV100011154; called by muse, mutect2, varscan2
- PKD1L2 | c.2688C>A p.L896= | Silent (SNP) | VAF 21/78 reads (27%) | catalogued as rs980962949, COSV100216832; called by muse, mutect2, varscan2
- PLEC | c.12963C>T p.S4321= (on ENST00000322810 / NM_201380.4; = p.S4211= on NM_000445.5) | Silent (SNP) | VAF 10/142 reads (7%) | catalogued as COSV100516707; called by muse, mutect2
- PLEKHN1 | c.1017T>C p.I339= (on ENST00000379409; = p.I287= on NM_032129.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 19/72 reads (26%) | catalogued as COSV100379221; called by muse, mutect2, varscan2
- PLTP | c.786G>T p.R262= | Silent (SNP) | VAF 13/109 reads (12%) | catalogued as COSV100819113; called by muse, mutect2, varscan2
- PPHLN1 | c.534C>A p.S178= | Silent (SNP) | VAF 10/110 reads (9%) | catalogued as COSV99872103; called by muse, mutect2
- PRPSAP2 | c.627G>A p.V209= | Silent (SNP) | VAF 24/96 reads (25%) | catalogued as COSV99264673; called by muse, mutect2, varscan2
- PTPRC | c.3054C>A p.I1018= | Silent (SNP) | VAF 8/85 reads (9%) | catalogued as COSV100722872, COSV61419273; called by muse, mutect2
- RBCK1 | c.285A>G p.P95= (on ENST00000356286 / NM_031229.4; = p.P53= on NM_006462.6) | Silent (SNP) | VAF 22/81 reads (27%) | catalogued as rs759216580, COSV100675895; called by muse, mutect2, varscan2
- RRBP1 | c.2679C>T p.H893= (on ENST00000377813 / NM_001365613.2; = p.H460= on NM_004587.3) | Silent (SNP) | VAF 7/57 reads (12%) | catalogued as COSV99854330; called by muse, mutect2, varscan2
- RUNDC3A | c.432G>T p.T144= | Silent (SNP) | VAF 17/91 reads (19%) | catalogued as COSV56637208, COSV99841957; called by muse, mutect2, varscan2
- S1PR5 | c.78C>T p.R26= | Silent (SNP) | VAF 23/57 reads (40%) | catalogued as COSV61013722; called by muse, mutect2, varscan2
- SCN5A | c.3147C>T p.I1049= | Silent (SNP) | VAF 37/45 reads (82%) | catalogued as rs867787484, COSV100349620; ClinVar: likely benign; called by muse, mutect2, varscan2
- SEC24C | c.1747C>T p.L583= | Silent (SNP) | VAF 7/48 reads (15%) | catalogued as rs767867892, COSV100227046; called by muse, mutect2, varscan2
- SERPINB13 | c.1074C>A p.A358= | Silent (SNP) | VAF 24/86 reads (28%) | catalogued as COSV99501163; called by muse, mutect2, varscan2
- SETD1A | c.2718C>A p.A906= | Silent (SNP) | VAF 65/313 reads (21%) | catalogued as COSV99353436; called by muse, mutect2, varscan2
- SGPP2 | c.825G>A p.A275= | Silent (SNP) | VAF 73/177 reads (41%) | catalogued as rs774810334, COSV58330132; called by muse, mutect2, varscan2
- SGSM3 | c.1026G>A p.S342= | Silent (SNP) | VAF 12/43 reads (28%) | catalogued as rs756842640, COSV50651842; called by muse, mutect2, varscan2
- SH3BP4 | c.2061C>T p.S687= | Silent (SNP) | VAF 42/78 reads (54%) | catalogued as rs765581617, COSV100749269; called by muse, mutect2, varscan2
- SLC16A6 | c.1419G>A p.P473= | Silent (SNP) | VAF 32/146 reads (22%) | catalogued as rs539141129, COSV100517364; called by muse, mutect2, varscan2
- SLC4A11 | c.846C>T p.R282= | Silent (SNP) | VAF 51/157 reads (32%) | catalogued as rs763721237, COSV101196082; called by muse, mutect2, varscan2
- SPATA4 | c.603C>A p.P201= | Silent (SNP) | VAF 24/68 reads (35%) | catalogued as COSV99709059; called by muse, mutect2, varscan2
- SPTBN2 | c.4326C>T p.I1442= | Silent (SNP) | VAF 15/52 reads (29%) | catalogued as rs1254241788, COSV100020009; called by muse, mutect2, varscan2
- TANK | c.1200A>G p.Q400= | Silent (SNP) | VAF 35/185 reads (19%) | catalogued as COSV99376369; called by muse, mutect2, varscan2
- TNPO2 | c.150C>T p.F50= | Silent (SNP) | VAF 17/53 reads (32%) | catalogued as rs201975298, COSV63509525; called by muse, mutect2, varscan2
- TOP2A | c.840T>C p.D280= | Silent (SNP) | VAF 11/101 reads (11%) | catalogued as COSV101396312; called by muse, mutect2, varscan2
- TP53INP2 | c.580C>A p.R194= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as COSV100750200; called by muse, mutect2
- TRIM3 | c.1479C>T p.S493= | Silent (SNP) | VAF 21/103 reads (20%) | catalogued as rs371131254; called by muse, mutect2, varscan2
- TRIP12 | c.63C>T p.A21= | Silent (SNP) | VAF 63/159 reads (40%) | catalogued as rs373813337, COSV99390693; called by muse, mutect2, varscan2
- TRPV4 | c.282G>A p.S94= | Silent (SNP) | VAF 12/51 reads (24%) | catalogued as rs1215886840, COSV99924878; called by muse, mutect2, varscan2
- TRUB2 | c.456C>A p.T152= | Silent (SNP) | VAF 37/101 reads (37%) | catalogued as COSV100867893; called by muse, mutect2, varscan2
- UCP3 | c.411A>G p.T137= | Silent (SNP) | VAF 23/74 reads (31%) | catalogued as rs1412349480, COSV100013032; called by muse, mutect2, varscan2
- WBP11 | c.651T>C p.R217= | Silent (SNP) | VAF 66/328 reads (20%) | catalogued as COSV99660795; called by muse, mutect2, varscan2
- WDSUB1 | c.744C>A p.S248= | Silent (SNP) | VAF 29/75 reads (39%) | catalogued as COSV100701856; called by muse, mutect2, varscan2
- WNK1 | c.4653C>A p.S1551= (on ENST00000315939 / NM_018979.4; = p.S1304= on NM_014823.3) | Silent (SNP) | VAF 122/504 reads (24%) | catalogued as COSV100267972, COSV60029675; called by muse, mutect2, varscan2
- WNT7A | c.372C>A p.T124= | Silent (SNP) | VAF 33/89 reads (37%) | catalogued as COSV99541532; called by muse, mutect2, varscan2
- WWC3 | c.1440G>A p.P480= | Silent (SNP) | VAF 18/20 reads (90%) | catalogued as rs748011259, COSV101081626; ClinVar: likely benign; called by muse, varscan2
- ZNF384 | c.1074C>T p.S358= | Silent (SNP) | VAF 24/58 reads (41%) | catalogued as COSV100158789; called by muse, mutect2, varscan2
- ZNF70 | c.270C>A p.L90= | Silent (SNP) | VAF 29/140 reads (21%) | catalogued as COSV100558913; called by muse, mutect2, varscan2
- ZNF821 | c.1065G>A p.R355= (on ENST00000425432 / NM_001376297.1; = p.R313= on NM_017530.2 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 27/113 reads (24%) | catalogued as COSV100546835; called by muse, mutect2, varscan2
- ZNF835 | c.1515A>G p.P505= | Silent (SNP) | VAF 23/217 reads (11%) | catalogued as rs1290540461, COSV101606386; called by muse, mutect2, varscan2
- ZSCAN20 | c.573C>T p.A191= | Silent (SNP) | VAF 10/43 reads (23%) | catalogued as rs146912787; called by muse, mutect2, varscan2
- AP000769.3 | chr11:65505003 C>T | 5'Flank (SNP) | VAF 8/34 reads (24%) | called by muse, mutect2, varscan2
- CHCHD4 | c.22+2688C>T | Intron (SNP) | VAF 36/44 reads (82%) | catalogued as rs1473917280, COSV99853906; called by muse, mutect2, varscan2
- CSNK1G2 | c.-266+11973C>T | Intron (SNP) | VAF 6/37 reads (16%) | catalogued as rs373006552; called by muse, mutect2, varscan2
- EZR | c.13-98G>A | Intron (SNP) | VAF 45/102 reads (44%) | catalogued as rs757804755; called by muse, mutect2, varscan2
- MKNK2 | c.*1783G>T | 3'UTR (SNP) | VAF 17/34 reads (50%) | catalogued as rs758971359, COSV99170346; called by muse, mutect2, varscan2
- NFATC4 | chr14:24367067 C>T | 5'Flank (SNP) | VAF 10/140 reads (7%) | catalogued as COSV99148372; called by muse, mutect2
- RFESD | c.*7dup | 3'UTR (INS) | VAF 14/60 reads (23%) | catalogued as rs766898555; called by mutect2, pindel, varscan2
- SERF2 | c.117-27C>A | Intron (SNP) | VAF 27/88 reads (31%) | catalogued as COSV99988568; called by muse, mutect2, varscan2
- TMEM132E | chr17:34579070 ins C | 5'Flank (INS) | VAF 56/185 reads (30%) | called by mutect2, pindel, varscan2
- TXNRD3 | n.588T>C | RNA (SNP) | VAF 19/98 reads (19%) | catalogued as COSV101275047; called by muse, mutect2, varscan2
- ZNF304 | c.161-730G>A | Intron (SNP) | VAF 18/51 reads (35%) | catalogued as rs751369202, COSV99988749; called by muse, mutect2, varscan2
